Somatic mutation profile of tumor specimen TCGA-86-8674-01A (aliquot TCGA-86-8674-01A-21D-2393-08) from TCGA case TCGA-86-8674, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Middle lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 50.6 years (18,479 days).
Specimen TCGA-86-8674-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 93f9639e-1efb-4f57-896e-c0bfff84982e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-86-8674-10A (Blood Derived Normal), aliquot TCGA-86-8674-10A-01D-2393-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8f6f8bf0-995b-4ce4-8700-aa120fb0043f

The open-access MAF lists 314 somatic variants for this specimen: 237 protein-altering or splice-affecting, 75 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 197, Silent 75, Nonsense Mutation 23, Frame Shift Del 9, Splice Site 6, Frame Shift Ins 1, 3'UTR 1, Splice Region 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.37G>T p.G13C | Missense Mutation (SNP) | VAF 8/42 reads (19%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs121913535, COSV55497378, COSV55502117, COSV55509530; ClinVar: pathogenic; called by muse, mutect2
- ADAMTS12 | c.3161C>G p.T1054S | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.202); catalogued as COSV100710615; called by muse, mutect2, varscan2
- ADCY1 | c.2273G>T p.G758V | Missense Mutation (SNP) | VAF 39/131 reads (30%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs371545964; called by muse, mutect2, varscan2
- ADCY9 | c.4033A>T p.T1345S | Missense Mutation (SNP) | VAF 33/122 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); catalogued as COSV99569714; called by muse, mutect2, varscan2
- ADGRL3 | c.1378G>T p.G460* (on ENST00000506720 / NM_001322402.2; = p.G392* on NM_015236.6) | Nonsense Mutation (SNP) | VAF 5/38 reads (13%) | catalogued as COSV101546980, COSV72266569; called by muse, mutect2, varscan2
- ADGRL3 | c.1379G>T p.G460V (on ENST00000506720 / NM_001322402.2; = p.G392V on NM_015236.6) | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV72270440; called by muse, mutect2, varscan2
- ADNP | c.3027T>G p.S1009R | Missense Mutation (SNP) | VAF 40/165 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV100823691; called by muse, mutect2, varscan2
- ADNP2 | c.395G>T p.R132L | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.086); catalogued as COSV100080709; called by muse, mutect2, varscan2
- AHNAK | c.14114A>T p.K4705M | Missense Mutation (SNP) | VAF 119/443 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99946759; called by muse, mutect2, varscan2
- AKAP6 | c.115G>T p.G39* | Nonsense Mutation (SNP) | VAF 27/73 reads (37%) | catalogued as COSV99799878; called by muse, mutect2, varscan2
- ALKBH2 | c.423C>G p.I141M | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as COSV99980308; called by muse, mutect2, varscan2
- ANO3 | c.2776G>T p.G926W | Missense Mutation (SNP) | VAF 46/166 reads (28%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.981); catalogued as COSV99881883; called by muse, mutect2, varscan2
- ATF7IP | c.1786C>T p.Q596* | Nonsense Mutation (SNP) | VAF 38/180 reads (21%) | catalogued as COSV53777044; called by muse, mutect2, varscan2
- B3GLCT | c.404C>T p.T135I | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100587237; called by muse, mutect2, varscan2
- B4GALNT3 | c.1780G>T p.V594L | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV99842771; called by muse, mutect2, varscan2
- B4GAT1 | c.104G>T p.G35V | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.636); catalogued as COSV100240196; called by muse, mutect2, varscan2
- BCL11A | c.2126C>G p.T709S (on ENST00000335712 / NM_001365609.1; = p.T743S on NM_018014.4) | Missense Mutation (SNP) | VAF 46/151 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.298); catalogued as COSV100185309; called by muse, mutect2, varscan2
- BDP1 | c.7711C>T p.Q2571* | Nonsense Mutation (SNP) | VAF 43/164 reads (26%) | catalogued as COSV62429007; called by muse, mutect2, varscan2
- BMPR1A | c.799G>T p.E267* | Nonsense Mutation (SNP) | VAF 18/77 reads (23%) | catalogued as COSV100923429; called by muse, mutect2, varscan2
- BMPR1B | c.511C>A p.P171T | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.341); catalogued as COSV99215636; called by muse, mutect2, varscan2
- BRSK1 | c.1634G>T p.G545V | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.086); catalogued as COSV100473873; called by muse, mutect2
- BTG4 | c.653G>T p.R218L | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.055); catalogued as COSV100604442; called by muse, mutect2, varscan2
- BUB1 | c.3063-1G>A p.X1021_splice | Splice Site (SNP) | VAF 4/23 reads (17%) | catalogued as COSV100241127; called by muse, mutect2
- C19orf44 | c.367G>T p.A123S | Missense Mutation (SNP) | VAF 37/109 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99522125; called by muse, mutect2, varscan2
- CACHD1 | c.3355C>T p.H1119Y | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as COSV99261946; called by muse, mutect2, varscan2
- CACNA1C | c.2860G>T p.A954S | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.992); catalogued as COSV100217575, COSV100218421; called by muse, mutect2, varscan2
- CACNB1 | c.478C>T p.P160S | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100703370; called by muse, mutect2
- CALN1 | c.271C>G p.Q91E (on ENST00000329008 / NM_001017440.3; = p.Q133E on NM_031468.4) | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as COSV100206181; called by muse, mutect2, varscan2
- CARS1 | c.2113G>T p.G705C | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99542454; called by muse, mutect2, varscan2
- CBY2 | c.1278G>T p.M426I | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.946); catalogued as COSV100137560; called by muse, mutect2, varscan2
- CCDC144A | c.2774G>T p.R925L | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.009); catalogued as COSV100138477; called by muse, mutect2, varscan2
- CCN6 | c.957C>A p.C319* | Nonsense Mutation (SNP) | VAF 33/81 reads (41%) | catalogued as rs1554314768, COSV100036965; called by muse, mutect2, varscan2
- CCNB1 | c.848G>T p.R283I | Missense Mutation (SNP) | VAF 64/233 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.749); catalogued as COSV99841258; called by muse, mutect2, varscan2
- CDH18 | c.1603C>A p.P535T | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.793); catalogued as COSV99933580; called by muse, varscan2
- CDH18 | c.1562C>G p.P521R | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV56910495, COSV99933583; called by muse, varscan2
- CENPF | c.4844G>A p.S1615N | Missense Mutation (SNP) | VAF 52/92 reads (57%) | SIFT tolerated (0.62); PolyPhen benign (0.024); catalogued as COSV100871633; called by muse, mutect2, varscan2
- CETP | c.1109C>A p.P370Q | Missense Mutation (SNP) | VAF 45/188 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.057); catalogued as COSV99569969; called by muse, mutect2, varscan2
- CFAP100 | c.1696C>A p.R566S | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100729153; called by mutect2, varscan2
- CFAP206 | c.499G>T p.A167S | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as COSV99739337; called by muse, mutect2, varscan2
- CHD7 | c.5180A>G p.Y1727C | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV101418148; called by muse, mutect2, varscan2
- CHN1 | c.946A>C p.K316Q | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.452); catalogued as COSV99789081; called by muse, mutect2, varscan2
- CLASP1 | c.1486C>T p.H496Y | Missense Mutation (SNP) | VAF 27/132 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99754075; called by muse, mutect2, varscan2
- CLCA4 | c.2177C>A p.T726N | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV100991092; called by muse, mutect2, varscan2
- CLEC1A | c.318G>T p.Q106H | Missense Mutation (SNP) | VAF 42/149 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.558); catalogued as COSV100191322; called by muse, mutect2, varscan2
- CLEC4G | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as COSV100183635; called by muse, mutect2, varscan2
- CMYA5 | c.4718T>C p.L1573S | Missense Mutation (SNP) | VAF 75/250 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV101483975; called by muse, mutect2, varscan2
- CNKSR2 | c.2131C>A p.P711T | Missense Mutation (SNP) | VAF 32/56 reads (57%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.894); catalogued as COSV99668030; called by muse, mutect2, varscan2
- COL1A2 | c.1214G>T p.R405L | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99799254; called by muse, mutect2, varscan2
- COPG1 | c.645C>G p.I215M | Missense Mutation (SNP) | VAF 67/249 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.133); catalogued as COSV100135504; called by muse, mutect2, varscan2
- COX20 | c.101T>C p.I34T | Missense Mutation (SNP) | VAF 25/140 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV100834661; called by muse, mutect2, varscan2
- CPS1 | c.2536C>T p.P846S | Missense Mutation (SNP) | VAF 55/219 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs200069420, COSV99242651; called by muse, mutect2, varscan2
- CSMD1 | c.10222G>A p.E3408K (on ENST00000520002; = p.E3407K on NM_033225.6) | Missense Mutation (SNP) | VAF 104/248 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.339); catalogued as COSV100146312; called by muse, varscan2
- CSMD1 | c.3576G>C p.W1192C (on ENST00000520002; = p.W1191C on NM_033225.6) | Missense Mutation (SNP) | VAF 43/114 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.7); catalogued as COSV100146314; called by muse, mutect2, varscan2
- CSN3 | c.544G>T p.A182S | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.575); catalogued as rs763259161, COSV100515293; called by muse, mutect2
- CTNNAL1 | c.527C>T p.A176V | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.53); PolyPhen benign (0.007); catalogued as COSV100336455; called by muse, mutect2, varscan2
- CUBN | c.2677A>T p.T893S | Missense Mutation (SNP) | VAF 44/179 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.04); catalogued as COSV100912403; called by muse, mutect2, varscan2
- DACT1 | c.499G>A p.G167R | Missense Mutation (SNP) | VAF 54/186 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100241754; called by muse, mutect2, varscan2
- DCAF4L2 | c.785G>A p.W262* | Nonsense Mutation (SNP) | VAF 68/151 reads (45%) | catalogued as rs755423315, COSV100150687; called by muse, mutect2, varscan2
- DMD | c.6439G>C p.E2147Q | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as CM138751, COSV100626703; called by muse, mutect2, varscan2
- DNAH7 | c.2194G>C p.A732P | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100414633, COSV56795226; called by muse, mutect2, varscan2
- DNM3 | c.400C>T p.L134F | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV100797989; called by muse, mutect2, varscan2
- DOCK4 | c.3298A>C p.S1100R | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.62); PolyPhen benign (0.023); catalogued as COSV101312825, COSV69854828; called by muse, mutect2, varscan2
- DSCAM | c.2594G>T p.C865F | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101259718; called by muse, mutect2, varscan2
- EEF1AKMT2 | c.181G>T p.G61* | Nonsense Mutation (SNP) | VAF 12/84 reads (14%) | catalogued as COSV64324726; called by muse, mutect2, varscan2
- EFCAB2 | c.386G>T p.G129V (on ENST00000366522; = p.G52V on NM_001290327.2) | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs766038229, COSV100833842; called by muse, mutect2
- EHD3 | c.1583C>A p.P528Q | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100434668; called by muse, mutect2, varscan2
- EPB41L5 | c.850G>C p.V284L | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99758522; called by muse, mutect2, varscan2
- EPHB3 | c.517C>T p.R173C | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1315526756, COSV57804008, COSV57808601; called by muse, mutect2, varscan2
- ERICH1 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.577); catalogued as COSV100032312; called by muse, mutect2, varscan2
- EVC2 | c.1747A>T p.S583C | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.042); catalogued as rs1222356750, COSV100185618; called by muse, mutect2, varscan2
- EXOC7 | c.1921G>T p.G641* (on ENST00000335146 / NM_001145297.4; = p.G559* on NM_015219.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 10/35 reads (29%) | catalogued as COSV100135077, COSV58034751; called by muse, mutect2, varscan2
- FARP1 | c.2452G>A p.E818K | Missense Mutation (SNP) | VAF 75/344 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.048); catalogued as rs778595557, COSV60333961; called by muse, mutect2, varscan2
- FBXO4 | c.899G>T p.R300I | Missense Mutation (SNP) | VAF 51/221 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.276); catalogued as COSV99715113; called by muse, mutect2, varscan2
- FEZF1 | c.1322C>A p.P441Q | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV100484465; called by muse, mutect2, varscan2
- FHDC1 | c.3011G>T p.R1004L | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.508); catalogued as COSV99471172; called by muse, mutect2, varscan2
- FLG | c.5531G>T p.S1844I | Missense Mutation (SNP) | VAF 182/1002 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.624); catalogued as COSV100911397; called by muse, mutect2, varscan2
- FNDC7 | c.1913G>T p.R638M | Missense Mutation (SNP) | VAF 86/284 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.66); catalogued as COSV99601075; called by muse, mutect2, varscan2
- FOXS1 | c.364G>T p.G122C | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as COSV99639647; called by muse, mutect2, varscan2
- FSTL5 | c.564T>G p.D188E | Missense Mutation (SNP) | VAF 42/149 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV100054057; called by muse, mutect2, varscan2
- FUZ | c.1237G>A p.A413T | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0.019); catalogued as COSV100571093; called by muse, mutect2, varscan2
- G6PC2 | c.1019C>A p.P340H | Missense Mutation (SNP) | VAF 47/175 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs2232327, COSV56373296; called by muse, mutect2, varscan2
- GCNT4 | c.1127G>C p.G376A | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.329); catalogued as COSV100466342; called by muse, mutect2, varscan2
- GCNT4 | c.1126G>T p.G376C | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV100466344; called by muse, mutect2, varscan2
- GPAT3 | c.137T>C p.L46S | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.188); catalogued as rs748363470, COSV100022917; called by muse, mutect2, varscan2
- GRIN2A | c.3449C>A p.P1150H | Missense Mutation (SNP) | VAF 51/215 reads (24%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.455); catalogued as COSV100409290; called by muse, mutect2, varscan2
- GRM7 | c.1895T>C p.L632P | Missense Mutation (SNP) | VAF 78/238 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100736095; called by muse, mutect2, varscan2
- HADHB | c.121A>G p.K41E | Missense Mutation (SNP) | VAF 46/160 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.021); catalogued as COSV100501959; called by muse, mutect2, varscan2
- HERC2 | c.11624G>T p.R3875L | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.973); catalogued as COSV99872483; called by muse, mutect2, varscan2
- HNRNPU | c.364G>T p.E122* | Nonsense Mutation (SNP) | VAF 7/55 reads (13%) | catalogued as COSV99310149; called by muse, mutect2, varscan2
- HPX | c.903G>T p.W301C | Missense Mutation (SNP) | VAF 58/189 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99793299; called by muse, mutect2, varscan2
- IGF2BP1 | c.1274G>T p.G425V | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51736211, COSV99288510; called by muse, mutect2, varscan2
- INPP5A | c.1009G>A p.E337K | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100704258; called by muse, mutect2, varscan2
- IQGAP2 | c.2570G>T p.G857V | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.065); catalogued as COSV57185441, COSV99166949; called by muse, mutect2, varscan2
- ITGA10 | c.2084A>G p.Q695R | Missense Mutation (SNP) | VAF 36/209 reads (17%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV100994832; called by muse, mutect2, varscan2
- ITGA4 | c.433G>T p.G145W | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99276064; called by muse, mutect2, varscan2
- ITGA8 | c.2420C>A p.P807Q | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.566); catalogued as COSV65232751; called by muse, mutect2, varscan2
- ITGA8 | c.2419C>A p.P807T | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.938); catalogued as rs371823194, COSV100959097; called by muse, mutect2, varscan2
- ITK | c.294C>A p.S98R | Missense Mutation (SNP) | VAF 35/137 reads (26%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.924); catalogued as COSV101439681; called by muse, mutect2, varscan2
- ITLN1 | c.158-1G>T p.X53_splice | Splice Site (SNP) | VAF 50/136 reads (37%) | catalogued as COSV58274453, COSV58274948; called by muse, mutect2, varscan2
- ITM2A | c.505A>T p.I169F | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.434); catalogued as COSV100964438; called by muse, mutect2, varscan2
- JAM3 | c.611T>A p.L204* | Nonsense Mutation (SNP) | VAF 17/56 reads (30%) | catalogued as COSV100137996; called by muse, mutect2, varscan2
- KCNJ12 | c.665A>T p.H222L | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV100054497; called by muse, mutect2, varscan2
- KEAP1 | c.1427G>T p.G476V | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99407608; called by muse, mutect2, varscan2
- KEL | c.2092C>A p.H698N | Missense Mutation (SNP) | VAF 42/114 reads (37%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs1042015, COSV100786995; called by muse, mutect2, varscan2
- KIAA1586 | c.1746C>G p.I582M | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.943); catalogued as COSV66057305; called by muse, mutect2, varscan2
- KIAA1958 | c.886C>T p.P296S | Missense Mutation (SNP) | VAF 94/352 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV100515979; called by muse, mutect2, varscan2
- KSR1 | c.1253C>A p.A418E (on ENST00000644974 / NM_001367810.1; = p.A281E on NM_014238.2) | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.211); catalogued as COSV99259057; called by muse, mutect2, varscan2
- LAMA4 | c.3370G>A p.D1124N (on ENST00000230538 / NM_001105206.3; = p.D1117N on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT tolerated (0.4); PolyPhen probably damaging (1); catalogued as COSV100038073; called by muse, mutect2, varscan2
- LAMB4 | c.2925C>A p.N975K | Missense Mutation (SNP) | VAF 45/140 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99223553; called by muse, mutect2, varscan2
- LCMT2 | c.1402A>T p.K468* | Nonsense Mutation (SNP) | VAF 37/129 reads (29%) | catalogued as COSV99980010; called by muse, mutect2, varscan2
- LGSN | c.994T>A p.S332T | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated (0.36); PolyPhen benign (0.048); catalogued as COSV101040430; called by muse, mutect2, varscan2
- LILRA2 | c.807G>T p.W269C | Missense Mutation (SNP) | VAF 33/124 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); catalogued as COSV99253148; called by muse, mutect2, varscan2
- LILRB4 | c.44T>C p.L15P | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.977); catalogued as rs1453153837, COSV99553680; called by muse, mutect2, varscan2
- LIPJ | c.291G>C p.L97F | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT tolerated (0.72); PolyPhen benign (0.024); catalogued as COSV100905911; called by muse, mutect2, varscan2
- LYST | c.9737T>C p.F3246S | Missense Mutation (SNP) | VAF 31/207 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.705); catalogued as COSV101088923; called by muse, mutect2, varscan2
- MACF1 | c.5527G>T p.A1843S | Missense Mutation (SNP) | VAF 29/130 reads (22%) | catalogued as COSV57120176, COSV99243153; called by muse, mutect2, varscan2
- MCM10 | c.2227G>T p.G743C (on ENST00000484800 / NM_182751.3; = p.G742C on NM_018518.5) | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as COSV101098043; called by muse, mutect2, varscan2
- MCM10 | c.2228G>T p.G743V (on ENST00000484800 / NM_182751.3; = p.G742V on NM_018518.5) | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.234); catalogued as COSV101098045; called by muse, mutect2, varscan2
- MED16 | c.671G>A p.G224D | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54132072, COSV99515702; called by muse, mutect2, varscan2
- MMP11 | c.455G>T p.R152L | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.531); catalogued as COSV53155968, COSV99303151; called by muse, mutect2, varscan2
- MMP13 | c.985G>T p.E329* | Nonsense Mutation (SNP) | VAF 28/122 reads (23%) | catalogued as COSV99506459; called by muse, mutect2, varscan2
- MMP13 | c.284G>T p.R95I | Missense Mutation (SNP) | VAF 46/197 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99506349, COSV99506464; called by muse, mutect2, varscan2
- MROH8 | c.1338G>T p.Q446H | Missense Mutation (SNP) | VAF 79/255 reads (31%) | SIFT tolerated (0.69); PolyPhen probably damaging (0.94); catalogued as COSV99456948, COSV99458001; called by muse, mutect2, varscan2
- MS4A10 | c.493-1G>T p.X165_splice | Splice Site (SNP) | VAF 6/27 reads (22%) | catalogued as COSV100382262; called by muse, mutect2, varscan2
- MSR1 | c.596del p.G199Afs*17 | Frame Shift Del (DEL) | VAF 24/126 reads (19%) | catalogued as COSV50525684, COSV50545817; called by mutect2, pindel, varscan2
- MYH8 | c.3961C>T p.Q1321* | Nonsense Mutation (SNP) | VAF 27/117 reads (23%) | catalogued as rs1268351167, COSV101238354; called by muse, mutect2, varscan2
- NALCN | c.400G>C p.D134H | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.91); catalogued as COSV51960026, COSV99214143; called by muse, mutect2, varscan2
- NFKBIA | c.906G>A p.E302= | Splice Region (SNP) | VAF 37/130 reads (28%) | catalogued as COSV99395052; called by muse, mutect2, varscan2
- NID2 | c.1094C>A p.T365N | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV99356270; called by muse, mutect2, varscan2
- NLRP12 | c.629C>G p.P210R | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV60743336, COSV60749442; called by muse, mutect2, varscan2
- NLRP14 | c.3180G>T p.Q1060H | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); catalogued as COSV100204807; called by muse, mutect2, varscan2
- NLRP3 | c.1277G>C p.S426T | Missense Mutation (SNP) | VAF 18/162 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV100275724; called by muse, mutect2, varscan2
- NT5C1B | c.1460A>T p.D487V (on ENST00000359846 / NM_001199086.2; = p.D427V on NM_033253.4) | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV100409936; called by muse, mutect2, varscan2
- NTRK3 | c.1038G>T p.K346N | Missense Mutation (SNP) | VAF 39/138 reads (28%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as COSV100446280, COSV58123328; called by muse, mutect2, varscan2
- NTRK3 | c.362G>T p.R121I | Missense Mutation (SNP) | VAF 45/156 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.326); catalogued as COSV100446282; called by muse, mutect2, varscan2
- NUP214 | c.1588C>G p.L530V | Missense Mutation (SNP) | VAF 38/136 reads (28%) | SIFT tolerated (0.33); PolyPhen benign (0.011); catalogued as COSV100845223; called by muse, mutect2, varscan2
- NYAP1 | c.1739G>T p.G580V | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.974); catalogued as COSV100278433; called by muse, mutect2, varscan2
- OLFM4 | c.39C>A p.F13L | Missense Mutation (SNP) | VAF 51/221 reads (23%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); catalogued as COSV54581101, COSV99524264; called by muse, mutect2, varscan2
- OR2M2 | c.74C>A p.T25K | Missense Mutation (SNP) | VAF 103/622 reads (17%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.683); catalogued as rs146796261, COSV100677211; called by muse, mutect2, varscan2
- OR4K17 | c.926G>T p.R309I | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.362); catalogued as COSV100210601, COSV59648596; called by muse, mutect2, varscan2
- OR52R1 | c.122C>A p.A41D | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as COSV100617687, COSV61887840; called by muse, mutect2, varscan2
- OR5H1 | c.511T>G p.S171A | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as COSV100641665; called by muse, mutect2
- OSR2 | c.494C>A p.P165H | Missense Mutation (SNP) | VAF 181/396 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV99882464; called by muse, mutect2, varscan2
- OTUD6A | c.749T>A p.V250D | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as COSV100610963; called by muse, mutect2, varscan2
- P2RX1 | c.718G>T p.G240C | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99844698; called by muse, mutect2, varscan2
- PAX5 | c.677G>T p.G226V | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.514); catalogued as rs975587046, COSV100814179, COSV63913217; called by muse, mutect2, varscan2
- PCDH11X | c.2227G>T p.D743Y | Missense Mutation (SNP) | VAF 68/154 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100010668; called by muse, mutect2, varscan2
- PCDH17 | c.2162C>A p.A721E | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV100931551, COSV64971415; called by muse, mutect2, varscan2
- PCDHB6 | c.400G>A p.A134T | Missense Mutation (SNP) | VAF 59/196 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV99170029; called by muse, mutect2, varscan2
- PCDHB9 | c.334G>T p.D112Y | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.025); catalogued as COSV53384667; called by muse, mutect2, varscan2
- PCDHGA1 | c.212G>T p.R71M | Missense Mutation (SNP) | VAF 54/230 reads (23%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.967); catalogued as COSV100965970; called by muse, mutect2, varscan2
- PHB | c.720G>C p.K240N | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV100303146; called by muse, mutect2, varscan2
- PIK3AP1 | c.1507C>T p.Q503* | Nonsense Mutation (SNP) | VAF 23/164 reads (14%) | catalogued as COSV100225666; called by muse, mutect2, varscan2
- PLA2G2D | c.401G>T p.W134L | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as COSV100908011; called by muse, mutect2, varscan2
- POF1B | c.948C>A p.Y316* | Nonsense Mutation (SNP) | VAF 16/28 reads (57%) | catalogued as COSV99426434; called by muse, mutect2, varscan2
- POLD2 | c.1255G>A p.E419K | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.057); catalogued as COSV99788630; called by muse, mutect2, varscan2
- PPID | c.197_198del p.L66Pfs*12 | Frame Shift Del (DEL) | VAF 10/71 reads (14%) | catalogued as rs1310420226; called by pindel, varscan2
- PPP1R26 | c.1510G>T p.G504W | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.539); catalogued as COSV100778038; called by muse, mutect2, varscan2
- PTPRD | c.3492G>A p.M1164I | Missense Mutation (SNP) | VAF 59/187 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs764232627, COSV61929709; called by muse, mutect2, varscan2
- PTPRO | c.3037C>A p.P1013T (on ENST00000281171 / NM_030667.3; = p.P985T on NM_002848.4) | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99840229; called by muse, mutect2, varscan2
- PTPRT | c.1157C>A p.P386Q | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100626435; called by mutect2, varscan2
- PUSL1 | c.848T>C p.L283P | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.194); catalogued as rs766185058, COSV100028182; called by muse, mutect2, varscan2
- RANBP2 | c.7324G>A p.A2442T | Missense Mutation (SNP) | VAF 108/577 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV99311772; called by muse, mutect2, varscan2
- RAVER1 | c.460C>G p.P154A | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.555); catalogued as COSV99348975; called by muse, mutect2, varscan2
- RB1CC1 | c.3460G>A p.E1154K | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.012); catalogued as COSV99211068; called by muse, mutect2, varscan2
- RBFOX2 | c.328A>T p.T110S (on ENST00000438146 / NM_001349995.2; = p.T40S on NM_014309.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/203 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.389); catalogued as COSV99455256; called by muse, mutect2, varscan2
- RELN | c.5254G>T p.V1752L | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV59029430; called by muse, mutect2, varscan2
- RHAG | c.492+1G>T p.X164_splice | Splice Site (SNP) | VAF 24/53 reads (45%) | catalogued as COSV100006484; called by muse, mutect2, varscan2
- ROR2 | c.1377G>T p.Q459H | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV100995680, COSV100996125; called by muse, mutect2, varscan2
- RRP1B | c.455A>T p.E152V | Missense Mutation (SNP) | VAF 79/258 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.842); catalogued as COSV100512970; called by muse, mutect2, varscan2
- RYR2 | c.2201C>T p.S734L | Missense Mutation (SNP) | VAF 99/336 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.119); catalogued as COSV100769317; called by muse, mutect2, varscan2
- RYR3 | c.2098T>A p.W700R | Missense Mutation (SNP) | VAF 81/298 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101212434; called by muse, mutect2, varscan2
- SARDH | c.527G>A p.G176D | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.942); catalogued as COSV100060626; called by muse, mutect2, varscan2
- SCG2 | c.838G>C p.D280H | Missense Mutation (SNP) | VAF 43/280 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV100544671, COSV59540102; called by muse, mutect2, varscan2
- SCG2 | c.661G>A p.E221K | Missense Mutation (SNP) | VAF 55/244 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as rs1209038419, COSV100544673; called by muse, mutect2, varscan2
- SEL1L | c.953A>G p.Y318C | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100377814; called by muse, mutect2, varscan2
- SIGLEC11 | c.1532G>C p.G511A | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV101389248, COSV70221946; called by muse, mutect2, varscan2
- SIPA1L2 | c.2374C>A p.H792N | Missense Mutation (SNP) | VAF 32/240 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99477794; called by muse, mutect2, varscan2
- SLC38A8 | c.805+2T>A p.X269_splice | Splice Site (SNP) | VAF 11/36 reads (31%) | catalogued as COSV100230399; called by muse, mutect2, varscan2
- SLC3A1 | c.148G>A p.G50S | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as rs1408497251, COSV99576954; called by muse, mutect2, varscan2
- SLC4A1 | c.2410C>T p.Q804* | Nonsense Mutation (SNP) | VAF 21/79 reads (27%) | catalogued as COSV99293210; called by muse, mutect2, varscan2
- SLC6A9 | c.1282G>T p.D428Y (on ENST00000360584 / NM_201649.4; = p.D374Y on NM_006934.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 49/156 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as rs771959344, COSV100746145; called by muse, mutect2, varscan2
- SLC7A13 | c.53del p.G18Afs*27 | Frame Shift Del (DEL) | VAF 35/157 reads (22%) | catalogued as rs376990177; called by mutect2, pindel, varscan2
- SLC9A2 | c.769T>C p.F257L | Missense Mutation (SNP) | VAF 94/296 reads (32%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.962); catalogued as COSV52133384; called by muse, varscan2
- SLITRK4 | c.1585G>T p.E529* | Nonsense Mutation (SNP) | VAF 92/143 reads (64%) | catalogued as COSV100567257, COSV100567382; called by muse, mutect2, varscan2
- SMYD2 | c.300G>T p.W100C | Missense Mutation (SNP) | VAF 24/148 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV65290495; called by muse, mutect2, varscan2
- SPAG6 | c.1123G>T p.A375S | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.521); catalogued as COSV100510150; called by muse, mutect2, varscan2
- SPATA33 | c.200C>T p.S67L | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0.027); catalogued as rs751571842, COSV99498320; called by muse, mutect2
- ST8SIA4 | c.520G>T p.V174L | Missense Mutation (SNP) | VAF 19/79 reads (24%) | PolyPhen possibly damaging (0.479); catalogued as COSV99185191; called by muse, mutect2, varscan2
- SYCP2L | c.1731C>A p.N577K | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT tolerated (0.25); PolyPhen benign (0.011); catalogued as COSV99305004; called by muse, mutect2, varscan2
- TCAIM | c.352A>G p.R118G | Missense Mutation (SNP) | VAF 32/131 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.085); catalogued as COSV100703232; called by muse, mutect2, varscan2
- TCL1A | c.269G>T p.S90I | Missense Mutation (SNP) | VAF 52/234 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.458); catalogued as COSV101268452; called by muse, mutect2, varscan2
- TECTA | c.624+1G>T p.X208_splice | Splice Site (SNP) | VAF 23/99 reads (23%) | catalogued as COSV50723017; called by muse, mutect2, varscan2
- TEKT3 | c.1015C>T p.Q339* | Nonsense Mutation (SNP) | VAF 27/147 reads (18%) | catalogued as COSV100106684, COSV58626955; called by muse, mutect2, varscan2
- TGIF2 | c.145C>G p.Q49E | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); catalogued as COSV100872287; called by muse, mutect2, varscan2
- TMEM169 | c.54G>T p.Q18H | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as COSV99824443; called by muse, mutect2, varscan2
- TMEM169 | c.55G>T p.G19C | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.614); catalogued as COSV99824446; called by muse, mutect2, varscan2
- TMEM176B | c.590A>T p.Q197L | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.089); catalogued as COSV100423517; called by muse, mutect2, varscan2
- TMLHE | c.208C>G p.R70G | Missense Mutation (SNP) | VAF 47/93 reads (51%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.565); catalogued as COSV100544703, COSV57688897; called by muse, mutect2, varscan2
- TNFSF15 | c.146G>T p.G49V | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.021); catalogued as COSV100928370; called by muse, mutect2, varscan2
- TNP2 | c.308C>G p.P103R | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.637); catalogued as rs765221473, COSV100449505; called by muse, mutect2, varscan2
- TNRC6A | c.3453G>A p.M1151I | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100169722; called by muse, mutect2, varscan2
- TOX2 | c.502G>T p.G168C (on ENST00000358131 / NM_001098798.2; = p.G117C on NM_032883.3) | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.72); catalogued as COSV100363683; called by muse, mutect2, varscan2
- TRAM1 | c.427G>T p.E143* | Nonsense Mutation (SNP) | VAF 66/161 reads (41%) | catalogued as COSV99140745; called by muse, mutect2, varscan2
- TRIM9 | c.419G>A p.R140Q | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.475); catalogued as COSV100031047; called by muse, mutect2, varscan2
- TSHB | c.331G>C p.D111H | Missense Mutation (SNP) | VAF 80/270 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as COSV99858981, COSV99859151; called by muse, mutect2, varscan2
- TSHR | c.2096G>T p.C699F | Missense Mutation (SNP) | VAF 54/194 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99991070, COSV99991526; called by muse, varscan2
- TSHZ3 | c.542A>T p.Q181L | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.452); catalogued as COSV99550656; called by muse, varscan2
- UBE4B | c.2865G>A p.M955I (on ENST00000343090 / NM_001105562.3; = p.M826I on NM_006048.5) | Missense Mutation (SNP) | VAF 41/178 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.146); catalogued as COSV99476217; called by muse, mutect2, varscan2
- USH2A | c.9264A>T p.E3088D | Missense Mutation (SNP) | VAF 89/261 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as COSV100232289, COSV100232562, COSV100237869; called by muse, mutect2, varscan2
- WDR91 | c.1282G>C p.V428L | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.651); catalogued as COSV100615647, COSV60371698; called by muse, mutect2, varscan2
- ZBED8 | c.520A>G p.I174V | Missense Mutation (SNP) | VAF 37/155 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.044); catalogued as COSV101283487; called by muse, mutect2, varscan2
- ZBED9 | c.3703G>T p.G1235* | Nonsense Mutation (SNP) | VAF 24/119 reads (20%) | catalogued as COSV101509193; called by muse, mutect2, varscan2
- ZCWPW1 | c.1234G>T p.E412* | Nonsense Mutation (SNP) | VAF 78/291 reads (27%) | catalogued as COSV99546397; called by muse, mutect2, varscan2
- ZFHX4 | c.7580C>A p.P2527Q | Missense Mutation (SNP) | VAF 44/243 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.095); catalogued as rs773883755, COSV50652805, COSV99260919; called by muse, varscan2
- ZNF208 | c.2016A>T p.K672N | Missense Mutation (SNP) | VAF 25/121 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV101236971; called by muse, mutect2, varscan2
- ZNF347 | c.1154G>C p.R385P | Missense Mutation (SNP) | VAF 47/170 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.006); catalogued as COSV100498221; called by muse, mutect2, varscan2
- ZNF462 | c.1240G>A p.E414K | Missense Mutation (SNP) | VAF 39/142 reads (27%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.019); catalogued as COSV99471356; called by muse, varscan2
- ZNF518B | c.1829A>T p.Q610L | Missense Mutation (SNP) | VAF 77/254 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.037); catalogued as COSV100456641; called by muse, mutect2, varscan2
- ZNF578 | c.541G>T p.E181* | Nonsense Mutation (SNP) | VAF 68/227 reads (30%) | catalogued as COSV101405035; called by muse, mutect2, varscan2
- ZNF626 | c.646C>A p.L216I | Missense Mutation (SNP) | VAF 36/129 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.627); catalogued as COSV101656970; called by muse, mutect2, varscan2
- ZNF676 | c.844G>A p.E282K (on ENST00000650058; = p.E250K on NM_001001411.3) | Missense Mutation (SNP) | VAF 29/191 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as COSV101236154; called by muse, varscan2
- ZNF718 | c.487A>T p.I163L | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.073); catalogued as COSV101210248; called by muse, mutect2, varscan2
- ZSCAN18 | c.697G>T p.D233Y | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99559279; called by muse, mutect2, varscan2
- COG2 | c.135_157del p.R46* | Frame Shift Del (DEL) | VAF 32/250 reads (13%) | called by mutect2, pindel
- IGKV1-17 | c.303G>C p.Q101H | Missense Mutation (SNP) | VAF 58/182 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- ITIH2 | c.1848_1870del p.L617Afs*13 | Frame Shift Del (DEL) | VAF 24/170 reads (14%) | called by mutect2, pindel
- KIR2DL4 | c.670G>T p.G224C (on ENST00000396284; = p.G185C on NM_001080770.2) | Missense Mutation (SNP) | VAF 76/265 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- MLLT6 | c.3070G>T p.A1024S | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.105); called by muse, mutect2
- NONO | c.315_318del p.H106Rfs*15 | Frame Shift Del (DEL) | VAF 50/132 reads (38%) | called by pindel, varscan2
- PEG3 | c.3596del p.G1199Vfs*8 | Frame Shift Del (DEL) | VAF 39/165 reads (24%) | called by mutect2, pindel, varscan2
- SCN3A | c.3534del p.F1179Sfs*4 | Frame Shift Del (DEL) | VAF 38/158 reads (24%) | called by mutect2, pindel*, varscan2
- SMARCA4 | c.1611del p.Y538Tfs*75 | Frame Shift Del (DEL) | VAF 58/183 reads (32%) | called by mutect2, pindel, varscan2
- SPATA31A3 | c.2754G>T p.Q918H | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); called by mutect2, varscan2
- TRBV19 | c.99G>T p.K33N | Missense Mutation (SNP) | VAF 46/162 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.15); called by muse, mutect2
- TRBV19 | c.100G>C p.E34Q | Missense Mutation (SNP) | VAF 45/162 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.187); called by muse, mutect2
- ZNF800 | c.461_462dup p.E155Lfs*38 | Frame Shift Ins (INS) | VAF 31/149 reads (21%) | called by mutect2, pindel, varscan2
- ANKRD55 | c.360C>T p.H120= | Silent (SNP) | VAF 39/142 reads (27%) | catalogued as COSV100591204; called by muse, mutect2, varscan2
- ARHGAP9 | c.1230C>T p.G410= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as COSV99953958; called by muse, mutect2, varscan2
- ASTN1 | c.2638C>A p.R880= | Silent (SNP) | VAF 28/133 reads (21%) | catalogued as COSV56067835, COSV99921068; called by muse, mutect2, varscan2
- CACNA1E | c.586C>A p.R196= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as COSV100701362, COSV100701897; called by muse, mutect2
- CACNB1 | c.480C>T p.P160= | Silent (SNP) | VAF 26/86 reads (30%) | catalogued as COSV100703368; called by muse, mutect2
- CALN1 | c.270C>A p.G90= (on ENST00000329008 / NM_001017440.3; = p.G132= on NM_031468.4) | Silent (SNP) | VAF 30/97 reads (31%) | catalogued as COSV100206183; called by muse, mutect2, varscan2
- CCDC27 | c.843C>A p.S281= | Silent (SNP) | VAF 14/64 reads (22%) | catalogued as COSV99622327; called by muse, mutect2
- CHRNA4 | c.201C>G p.G67= | Silent (SNP) | VAF 11/62 reads (18%) | catalogued as COSV100937235; called by muse, mutect2, varscan2
- CILP2 | c.3189T>C p.T1063= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as COSV99364526; called by muse, mutect2, varscan2
- CLCA4 | c.2178C>A p.T726= | Silent (SNP) | VAF 23/94 reads (24%) | catalogued as COSV100991093; called by muse, mutect2, varscan2
- CLN5 | c.51G>T p.A17= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV101080267; called by muse, mutect2
- CLN5 | c.522C>T p.H174= | Silent (SNP) | VAF 63/261 reads (24%) | catalogued as COSV101080269; called by muse, mutect2, varscan2
- CNTN6 | c.1137A>G p.S379= | Silent (SNP) | VAF 20/86 reads (23%) | catalogued as COSV100610465; called by muse, mutect2, varscan2
- COG3 | c.879C>T p.F293= | Silent (SNP) | VAF 34/184 reads (18%) | catalogued as COSV100596466; called by muse, mutect2, varscan2
- COIL | c.663T>G p.G221= | Silent (SNP) | VAF 42/160 reads (26%) | catalogued as COSV99538066; called by muse, mutect2, varscan2
- CSF2RB | c.180C>A p.T60= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as COSV99453616; called by mutect2, varscan2
- DLGAP2 | c.1563C>A p.T521= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as COSV101421586; called by muse, mutect2
- DNAH2 | c.8205G>T p.V2735= | Silent (SNP) | VAF 61/166 reads (37%) | catalogued as COSV101209156; called by muse, mutect2, varscan2
- DNAH9 | c.11175G>A p.E3725= | Silent (SNP) | VAF 54/219 reads (25%) | catalogued as COSV99305180; called by muse, mutect2, varscan2
- DPY19L2 | c.123C>A p.A41= | Silent (SNP) | VAF 25/87 reads (29%) | catalogued as COSV100116649; called by muse, mutect2, varscan2
- DSC1 | c.1656G>T p.V552= | Silent (SNP) | VAF 16/56 reads (29%) | catalogued as COSV99937481; called by muse, mutect2, varscan2
- ENTPD2 | c.1350C>T p.A450= (on ENST00000355097 / NM_203468.3; = p.A427= on NM_001246.4) | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as rs763590098, COSV100445713; called by muse, mutect2, varscan2
- EPSTI1 | c.597A>T p.T199= | Silent (SNP) | VAF 75/248 reads (30%) | catalogued as COSV100552786; called by muse, mutect2, varscan2
- EXOC7 | c.1920G>T p.P640= (on ENST00000335146 / NM_001145297.4; = p.P558= on NM_015219.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as COSV100134920; called by muse, mutect2, varscan2
- FAM83G | c.1032C>T p.L344= | Silent (SNP) | VAF 34/149 reads (23%) | catalogued as rs371247127; called by muse, mutect2, varscan2
- FANCM | c.744A>T p.P248= | Silent (SNP) | VAF 33/154 reads (21%) | catalogued as COSV99950847; called by muse, mutect2, varscan2
- FEZF1 | c.1323G>A p.P441= | Silent (SNP) | VAF 14/67 reads (21%) | catalogued as rs775695735, COSV58658357; called by muse, mutect2, varscan2
- FOXP1 | c.981C>G p.L327= | Silent (SNP) | VAF 25/106 reads (24%) | catalogued as COSV100561387; called by muse, mutect2, varscan2
- GFI1B | c.801C>A p.T267= | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as COSV100254073; called by muse, mutect2, varscan2
- GRM8 | c.450C>A p.V150= | Silent (SNP) | VAF 43/148 reads (29%) | catalogued as COSV100281919; called by muse, mutect2, varscan2
- ITPR3 | c.2205C>T p.L735= | Silent (SNP) | VAF 44/131 reads (34%) | catalogued as rs757011659, COSV100967218; called by muse, mutect2, varscan2
- KLHDC7B | c.1447C>A p.R483= (on ENST00000395676; = p.R1124= on NM_138433.5) | Silent (SNP) | VAF 25/105 reads (24%) | catalogued as COSV67465254; called by muse, mutect2, varscan2
- LAMA2 | c.2884A>C p.R962= | Silent (SNP) | VAF 36/70 reads (51%) | catalogued as COSV101370328; called by muse, mutect2, varscan2
- LILRB4 | c.45G>T p.L15= | Silent (SNP) | VAF 25/113 reads (22%) | catalogued as COSV99553682; called by muse, mutect2, varscan2
- LRP2 | c.8346C>T p.A2782= | Silent (SNP) | VAF 23/96 reads (24%) | catalogued as COSV99787577; called by muse, mutect2, varscan2
- LRP4 | c.1437C>T p.R479= | Silent (SNP) | VAF 23/72 reads (32%) | catalogued as rs141108617; called by muse, mutect2, varscan2
- MAPK8 | c.906G>T p.L302= | Silent (SNP) | VAF 39/114 reads (34%) | catalogued as COSV64411391; called by muse, mutect2, varscan2
- MLXIP | c.2226C>T p.L742= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as COSV100038609; called by muse, mutect2, varscan2
- MORC1 | c.28C>A p.R10= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as COSV51720722, COSV99225828; called by muse, mutect2
- NAV3 | c.3850C>A p.R1284= | Silent (SNP) | VAF 16/54 reads (30%) | catalogued as COSV99889205; called by muse, mutect2, varscan2
- NAV3 | c.5058C>A p.G1686= | Silent (SNP) | VAF 25/111 reads (23%) | catalogued as COSV99889209; called by muse, mutect2, varscan2
- NDN | c.600G>A p.V200= | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as COSV100086373; called by muse, mutect2, varscan2
- NLRP4 | c.2232T>A p.A744= | Silent (SNP) | VAF 42/156 reads (27%) | catalogued as COSV100016025; called by muse, mutect2, varscan2
- NRXN1 | c.1098C>A p.A366= | Silent (SNP) | VAF 20/66 reads (30%) | catalogued as COSV100454345; called by muse, mutect2, varscan2
- NXF3 | c.867C>T p.F289= | Silent (SNP) | VAF 83/154 reads (54%) | catalogued as COSV101221915; called by muse, mutect2, varscan2
- OPRL1 | c.741G>T p.L247= | Silent (SNP) | VAF 32/144 reads (22%) | catalogued as COSV100402042; called by muse, mutect2, varscan2
- OR10T2 | c.621A>T p.V207= | Silent (SNP) | VAF 30/109 reads (28%) | catalogued as COSV100554910; called by muse, mutect2, varscan2
- OR2D2 | c.60G>T p.G20= | Silent (SNP) | VAF 33/126 reads (26%) | catalogued as COSV100203781; called by muse, mutect2, varscan2
- OR2L8 | c.399C>A p.I133= | Silent (SNP) | VAF 82/503 reads (16%) | catalogued as COSV100594102; called by muse, mutect2, varscan2
- OR2T34 | c.366C>A p.A122= | Silent (SNP) | VAF 21/136 reads (15%) | catalogued as COSV100170331; called by muse, mutect2, varscan2
- OR2T4 | c.54G>A p.L18= | Silent (SNP) | VAF 23/125 reads (18%) | called by muse, varscan2
- OR6B2 | c.609C>A p.A203= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as COSV99401352; called by muse, mutect2, varscan2
- PADI1 | c.1278C>T p.P426= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as rs142341928, COSV100969053; called by mutect2, varscan2
- PCDHA1 | c.1353C>T p.N451= | Silent (SNP) | VAF 46/135 reads (34%) | catalogued as rs143660641; called by muse, mutect2, varscan2
- PCDHGA3 | c.891G>C p.V297= | Silent (SNP) | VAF 13/56 reads (23%) | catalogued as COSV99535113; called by muse, mutect2, varscan2
- PCDHGB3 | c.303G>T p.T101= | Silent (SNP) | VAF 94/377 reads (25%) | catalogued as COSV99535115; called by muse, mutect2, varscan2
- PCDHGB7 | c.1857G>T p.L619= | Silent (SNP) | VAF 35/132 reads (27%) | catalogued as COSV99535120; called by muse, mutect2, varscan2
- PDZD2 | c.4119C>T p.S1373= | Silent (SNP) | VAF 3/26 reads (12%) | catalogued as COSV99224542; called by muse, mutect2
- PHF21A | c.507C>T p.L169= | Silent (SNP) | VAF 32/113 reads (28%) | catalogued as rs1211900919, COSV99138327; called by muse, mutect2, varscan2
- PRKACG | c.924G>A p.E308= | Silent (SNP) | VAF 50/132 reads (38%) | catalogued as COSV99598498; called by muse, mutect2, varscan2
- REPIN1 | c.1002C>A p.A334= | Silent (SNP) | VAF 4/10 reads (40%) | called by muse, mutect2
- SACS | c.11136A>T p.T3712= | Silent (SNP) | VAF 41/158 reads (26%) | catalogued as COSV101207327; called by muse, mutect2, varscan2
- SLC12A2 | c.3207G>T p.R1069= | Silent (SNP) | VAF 45/157 reads (29%) | catalogued as COSV99320891; called by muse, mutect2, varscan2
- SLC26A3 | c.678C>A p.L226= | Silent (SNP) | VAF 24/72 reads (33%) | catalogued as COSV100384974, COSV60640676; called by muse, mutect2, varscan2
- ST3GAL1 | c.150G>C p.L50= | Silent (SNP) | VAF 19/92 reads (21%) | catalogued as COSV100171963; called by muse, mutect2, varscan2
- TFAP2D | c.648C>A p.G216= | Silent (SNP) | VAF 21/161 reads (13%) | catalogued as COSV99145831; called by muse, mutect2, varscan2
- TJP2 | c.1926G>A p.L642= | Silent (SNP) | VAF 33/119 reads (28%) | catalogued as COSV99600923; called by muse, mutect2, varscan2
- TJP3 | c.2346C>T p.N782= | Silent (SNP) | VAF 3/15 reads (20%) | catalogued as rs756861985, COSV99515942; called by muse, mutect2
- TRIM9 | c.420G>T p.R140= | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as COSV100031041; called by muse, mutect2, varscan2
- TSHR | c.2175C>A p.T725= | Silent (SNP) | VAF 39/141 reads (28%) | catalogued as rs1414815539, COSV53315611; called by muse, varscan2
- TUBB8 | c.753G>T p.R251= | Silent (SNP) | VAF 19/83 reads (23%) | catalogued as COSV100226005; called by muse, varscan2
- USP4 | c.621A>G p.L207= | Silent (SNP) | VAF 48/195 reads (25%) | catalogued as COSV55540423; called by muse, mutect2, varscan2
- VSIG4 | c.738C>A p.T246= | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as COSV101038124, COSV66073406; called by muse, mutect2, varscan2
- WASHC2A | c.2178G>C p.L726= | Silent (SNP) | VAF 45/170 reads (26%) | catalogued as COSV99254582; called by muse, mutect2, varscan2
- WDR1 | c.1485G>T p.V495= (on ENST00000382452; = p.V355= on NM_005112.5) | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as COSV101221090; called by muse, mutect2, varscan2
- TRIM51 | c.*2C>A | 3'UTR (SNP) | VAF 60/235 reads (26%) | catalogued as COSV99792425; called by muse, mutect2, varscan2
- ZNF211 | c.91-567G>C | Intron (SNP) | VAF 10/64 reads (16%) | catalogued as COSV99560174; called by muse, mutect2, varscan2
